Surgical pathology report (de-identified scan), TCGA case TCGA-W2-A7HB, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Medical College of Wisconsin, specimen TCGA-W2-A7HB-01A (Primary Tumor).

[page 1 of 2]
Results History

SURG PATH FINAL REPORT

Entry Information

Entry Date and Time

Lab Status
Final result

Entered by

Component Results

SURG PATH FINAL REPORT:

Accession #:

Specimen:

Date of Procedure:

Performing Clinician:

A. Right cortical sparing adrenal

Clinical Notes:

Pre-op diagnosis: Pheochromocytoma.

Diagnosis:

A. Adrenal gland, right, cortical sparing adrenalectomy:
- Pheochromocytoma, see comment.

Comment: Sections show that the adrenal medulla is completely replaced with neoplastic chromaffin cells that form two discrete nodules (1.0 and 0.4 cm). There are neoplastic cells focally present at the cauterized resection margin, which may be expected in a cortical sparing adrenalectomy. The neoplastic cells are arranged in atypically large nests with focal spindling and pleomorphism. There is no evidence of capsular invasion, vascular invasion, necrosis, hyperchromasia, prominent nucleoli, or increased mitotic activity. The presence of large nests and focal spindling suggest the potential for malignant biologic behavior. Clinical correlation is required.

(Electronically signed by)
Verified:

Gross:

A. The specimen is labeled "right cortical sparing adrenal." Received in _____ and transferred to formalin is a 5.54 gm, 3.7 x 3.0 x 1.5 cm portion of markedly disrupted adrenal gland. In addition, separate within the container, is a 3.0 x 0.8 x 0.4 cm portion of pink-tan tissue. The outer surface is markedly disrupted with cautery artifact. A possible cut surface of adrenal gland

ICD-O-3
Pheochromocytoma NOS
8700/0
Site @ Adrenal gland NOS
C74.9
JW 9/4/13

[page 2 of 2]
[REDACTED]

is identified. This portion of cut surface is inked blue and the remainder of the outer surface is inked black. The specimen is sectioned to reveal a 1.0 x 1.0 x 1.0 cm soft white nodular circumscribed mass that abuts the black inked outer surface and the blue inked cut surface. In addition, there is a 0.4 x 0.4 x 0.3 cm firm white nodule present 1.0

Accession #:

cm from the first described nodule abutting the outer black inked surface of the specimen and 2.2 cm from the blue inked cut surface. The remaining adrenal gland contains a 0.1 cm yellow cortex with a pink-tan medulla. The specimen is entirely submitted as follows:

Cassette Designation:

A1 Smaller described nodule submitted entirely
A2 Intervening adrenal between both nodules
A3-4 Larger adrenal nodule submitted entirely (closest blue and black margins in cassette A4)
A5 Additional unremarkable adrenal
A6 Distal blue inked cut surface of adrenal
A7 Entire tissue separate in cassette

Fresh tissue saved for tissue bank.

Microscopic:

A histological examination has been performed.

Administrative Notes:

CPT:

No charge codes are associated with this case.

Entry Information

Entry Date and Time

Lab Status
In process

Entered by

Source: NCI Genomic Data Commons file 27876b01-5ac0-42f2-8741-30814d0b9279 (TCGA-W2-A7HB.89F892DC-13B8-49BC-A06B-E4EC6179C068.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).